Somatic mutation profile of tumor specimen TARGET-40-NAAGJP-01A (aliquot TARGET-40-NAAGJP-01A-01D) from TARGET case TARGET-40-NAAGJP, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 30.0 years (10,941 days).
Specimen TARGET-40-NAAGJP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee7e5caa-fb4a-4c31-9a23-c9c08b2b8956.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJP-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88185fd8-6622-477d-9778-2e49888bb2fd

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 26/203 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs200574267; called by muse, mutect2, varscan2
- ATRX | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV64873866; called by muse, mutect2, varscan2
- KCNA1 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs370669088; called by muse, mutect2, varscan2
- LAMA2 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs376580266, COSV101369833; called by muse, mutect2, varscan2
- LRRC27 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs113966513; called by muse, mutect2, varscan2
- PTGS1 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753219685, COSV56293178; called by muse, mutect2, varscan2
- DERPC | c.607G>T p.V203F | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.118); called by muse, mutect2
- LCORL | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- TRPC3 | c.1946A>G p.D649G (on ENST00000379645 / NM_001366479.2; = p.D576G on NM_003305.2) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH1 | c.2046G>A p.E682= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs753209043; ClinVar: likely benign; called by muse, mutect2, varscan2
- MFSD8 | c.1365C>T p.G455= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- PCLO | c.48G>T p.L16= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ADGRE4P | n.1323G>T | RNA (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
